Somatic mutation profile of tumor specimen ALCH-B253-TTP1-A (aliquot ALCH-B253-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B253, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,184 days).
Specimen ALCH-B253-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 615299bd-8c01-4ce0-93d9-84b9c49d04d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B253-NB1-A (Blood Derived Normal), aliquot ALCH-B253-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fe54fc6-32d8-4052-84fd-b4c79e26cfb0

The open-access MAF lists 156 somatic variants for this specimen: 92 protein-altering or splice-affecting, 46 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 46, Nonsense Mutation 9, Intron 9, RNA 4, 3'UTR 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, 5'UTR 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 19/208 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2
- ABCC6 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 47/466 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs72650697, CM073953, COSV52741670, COSV99227993; called by muse, mutect2, varscan2
- AC005833.1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); catalogued as rs781382912, COSV52899187; called by muse, mutect2, varscan2
- ADGRL3 | c.1406C>T p.A469V (on ENST00000506720 / NM_001322402.2; = p.A401V on NM_015236.6) | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1056694118; called by muse, mutect2
- AKR1B1 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 32/323 reads (10%) | catalogued as COSV53647405; called by muse, mutect2, varscan2
- ART3 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61916380; called by muse, mutect2
- ATG13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1475125210; called by muse, mutect2, varscan2
- C12orf50 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 20/246 reads (8%) | catalogued as rs200677856, COSV53893431, COSV53897104; called by muse, mutect2
- CPXM1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs776351140, COSV66045544; called by muse, mutect2
- CSPP1 | c.3253G>C p.E1085Q (on ENST00000676605; = p.E1044Q on NM_024790.6) | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as rs912659106; called by muse, mutect2, varscan2
- DNAH2 | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs771196566; called by muse, varscan2
- DNAH6 | c.10543G>C p.E3515Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.309); catalogued as rs1382961395; called by muse, varscan2
- FOXL1 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752797610; called by muse, mutect2, varscan2
- FSCB | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100469180; called by muse, mutect2, varscan2
- GREB1L | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV52555847; called by muse, mutect2
- HCN2 | c.2648C>A p.S883* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as rs1287730190; called by muse, mutect2
- ISYNA1 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1359874214; called by muse, mutect2, varscan2
- KDM6A | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 19/334 reads (6%) | catalogued as COSV65037736; called by muse, mutect2
- KIAA1549L | c.199C>A p.L67I (on ENST00000321505; = p.L364I on NM_012194.3) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV55777447; called by muse, mutect2, varscan2
- MAST1 | c.3865G>A p.V1289M | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.779); catalogued as rs761014554; called by muse, mutect2
- MUC16 | c.13894G>A p.E4632K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs753922997; called by muse, varscan2
- MYOT | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV53514818; called by muse, mutect2
- NUDT21 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.587); catalogued as COSV55859472; called by muse, mutect2, varscan2
- OR5T1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV57302162; called by muse, mutect2, varscan2
- OR5T1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs747076798; called by muse, mutect2
- PCDHGB4 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.367); catalogued as rs1022856135; called by muse, mutect2
- PKHD1 | c.7589C>G p.S2530C | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100582522; called by muse, mutect2
- RBM12 | c.1681C>T p.L561F | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.179); catalogued as rs1473709570; called by muse, mutect2, varscan2
- SDC2 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230047; called by muse, mutect2
- SETD2 | c.6837dup p.V2280Cfs*89 | Frame Shift Ins (INS) | VAF 50/280 reads (18%) | catalogued as rs1322967408; called by mutect2, pindel, varscan2
- SLK | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as COSV59827600; called by muse, mutect2
- SLK | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV100211822, COSV59823665; called by muse, mutect2, varscan2
- SMARCA2 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1357432914; called by muse, mutect2, varscan2
- SON | c.6143A>G p.K2048R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as COSV51661495; called by muse, mutect2
- TRAK1 | c.1963+3G>A | Splice Region (SNP) | VAF 41/433 reads (9%) | catalogued as rs1057052282; called by muse, mutect2
- ZBTB20 | c.1324G>A p.D442N (on ENST00000474710 / NM_001164342.2; = p.D369N on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.811); catalogued as COSV61859361; called by muse, mutect2
- ZNF236 | c.5467C>T p.R1823W | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs201773442; called by muse, mutect2, varscan2
- ZNF616 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV57511241; called by muse, mutect2, varscan2
- ZNF676 | c.1591C>A p.H531N (on ENST00000650058; = p.H499N on NM_001001411.3) | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68094309; called by muse, mutect2, varscan2
- ADAMTS16 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- AGL | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30B | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- ATP8A1 | c.2523G>T p.K841N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAHCC1 | c.2831T>C p.F944S | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.733); called by muse, mutect2
- BUB1B | c.3046G>T p.A1016S | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CALML3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CCR10 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLEC4F | c.1090T>G p.S364A | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLMP | c.680-1G>C p.X227_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | called by muse, varscan2
- DHTKD1 | c.2252G>A p.R751K | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DLL3 | c.1689G>C p.W563C | Missense Mutation (SNP) | VAF 56/523 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMTF1 | c.1211_1212del p.K404Rfs*3 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- EIF2S3B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ELFN1 | c.2342G>C p.R781T | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- EPHA10 | c.2685G>C p.Q895H | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- EVC | c.2598C>G p.F866L | Missense Mutation (SNP) | VAF 55/629 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2
- GMPPA | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 16/451 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HTR1D | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2
- LAMC2 | c.1617G>C p.L539F | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MAGEB6B | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEI1 | c.3032C>G p.S1011C | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTUS2 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- MUC3A | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- NINL | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NSD2 | c.3387_3388insT p.A1130Cfs*20 | Frame Shift Ins (INS) | VAF 43/225 reads (19%) | called by mutect2, pindel, varscan2
- PCDH10 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.543); called by muse, mutect2
- PCDH15 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDH19 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 54/536 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA5 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PCSK4 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- PDE4DIP | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 17/235 reads (7%) | called by muse, mutect2
- PIKFYVE | c.1595C>G p.S532C | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RB1CC1 | c.3220A>G p.I1074V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNPEPL1 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SEMA3E | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.302); called by muse, mutect2
- SETD2 | c.4091del p.K1364Rfs*9 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- SLC13A1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SLC29A4 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLC7A14 | c.1657A>T p.K553* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2
- SLIRP | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); called by muse, varscan2
- SPART | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SPTBN5 | c.415A>T p.I139F | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEFF1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TRIM61 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- XAGE3 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- XPA | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ZNF273 | c.1263G>C p.K421N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZNF577 | c.700A>T p.R234* | Nonsense Mutation (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- ZNF614 | c.1592G>A p.R531K | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACLY | c.153C>T p.L51= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs1555634035; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2070C>T p.D690= | Silent (SNP) | VAF 63/563 reads (11%) | catalogued as rs200102058; called by muse, mutect2, varscan2
- ALOX12 | c.1443C>A p.L481= | Silent (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2
- APOA1 | c.414C>G p.L138= | Silent (SNP) | VAF 37/341 reads (11%) | called by muse, mutect2, varscan2
- ARMC9 | c.1566G>C p.V522= | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, varscan2
- ATP9A | c.306C>G p.L102= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs773378534; called by muse, mutect2, varscan2
- CAMKMT | c.523C>T p.L175= | Silent (SNP) | VAF 28/279 reads (10%) | catalogued as COSV65930334; called by muse, mutect2
- CD248 | c.2121C>T p.I707= | Silent (SNP) | VAF 29/338 reads (9%) | catalogued as rs770490701, COSV60936686; called by muse, mutect2
- COL11A1 | c.1117C>T p.L373= | Silent (SNP) | VAF 29/316 reads (9%) | called by muse, mutect2
- COL4A6 | c.4644C>A p.T1548= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV57860773; called by muse, mutect2, varscan2
- DDX24 | c.678C>T p.A226= | Silent (SNP) | VAF 13/82 reads (16%) | called by mutect2, varscan2
- ELMO1 | c.1527G>A p.L509= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- ERMP1 | c.1905G>A p.S635= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs546666441; called by muse, mutect2
- EVPLL | c.147C>G p.L49= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- FZD10 | c.1263C>T p.F421= | Silent (SNP) | VAF 34/281 reads (12%) | called by muse, mutect2, varscan2
- GDF10 | c.990G>A p.A330= | Silent (SNP) | VAF 11/185 reads (6%) | catalogued as rs782407138; called by muse, mutect2
- GNAS | c.1902C>G p.L634= | Silent (SNP) | VAF 63/507 reads (12%) | called by muse, mutect2, varscan2
- GRXCR1 | c.558C>T p.D186= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs367885687; called by muse, mutect2, varscan2
- HECTD4 | c.8661C>T p.L2887= | Silent (SNP) | VAF 24/367 reads (7%) | called by muse, mutect2
- HEPH | c.723C>G p.L241= (on ENST00000343002; = p.L295= on NM_138737.5) | Silent (SNP) | VAF 20/213 reads (9%) | catalogued as COSV57967519; called by muse, mutect2
- LEP | c.285C>T p.I95= | Silent (SNP) | VAF 34/472 reads (7%) | catalogued as rs200061184; called by muse, mutect2
- LILRA6 | c.282G>C p.G94= | Silent (SNP) | VAF 64/653 reads (10%) | called by muse, mutect2
- LIPH | c.129G>C p.L43= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- MACF1 | c.20967T>C p.L6989= (on ENST00000372915; = p.L5034= on NM_012090.5) | Silent (SNP) | VAF 44/220 reads (20%) | called by muse, varscan2
- MAP3K14 | c.303C>T p.F101= | Silent (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- MUC12 | c.15051T>C p.H5017= (on ENST00000379442; = p.H4874= on NM_001164462.1) | Silent (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- NCOR2 | c.3921C>G p.P1307= | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- NLRP3 | c.2781C>T p.I927= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as COSV60227563; called by muse, mutect2, varscan2
- NPR1 | c.2082C>T p.T694= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1160495569; called by muse, mutect2
- PHKG1 | c.471C>T p.L157= | Silent (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- POC1A | c.333C>T p.F111= | Silent (SNP) | VAF 24/239 reads (10%) | catalogued as COSV56591835; called by muse, mutect2, varscan2
- PPP1R9B | c.333G>A p.L111= | Silent (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2
- PSMD12 | c.96G>C p.A32= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV62065163; called by muse, mutect2
- QDPR | c.480C>G p.L160= | Silent (SNP) | VAF 45/269 reads (17%) | catalogued as COSV55549115; called by muse, mutect2, varscan2
- SCO2 | c.186G>A p.L62= | Silent (SNP) | VAF 36/349 reads (10%) | catalogued as rs28450572, COSV52689567; called by muse, mutect2
- SHROOM4 | c.2100C>T p.T700= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- SLC25A4 | c.51C>A p.V17= | Silent (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- SLC39A11 | c.462G>A p.E154= (on ENST00000542342 / NM_001159770.2; = p.E147= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs756830187, COSV55280888; called by muse, mutect2, varscan2
- SLC5A8 | c.1743A>C p.P581= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV101610533; called by muse, mutect2
- SLC6A13 | c.801C>T p.Y267= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- TFAP2D | c.942C>A p.A314= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as COSV50418160; called by muse, mutect2, varscan2
- TLN1 | c.1245G>A p.E415= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- TNS1 | c.4806C>G p.L1602= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs776492731; called by muse, mutect2, varscan2
- WDR97 | c.1932G>A p.P644= | Silent (SNP) | VAF 52/637 reads (8%) | called by muse, mutect2
- ZBTB40 | c.279C>T p.I93= | Silent (SNP) | VAF 42/465 reads (9%) | catalogued as rs1276708397; called by muse, mutect2
- ZNF45 | c.1947C>T p.F649= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- AP1S1 | c.3+97C>G | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1485604338; called by muse, mutect2, varscan2
- ARPC5 | c.*15G>T | 3'UTR (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- C5orf60 | n.2446C>G | RNA (SNP) | VAF 19/132 reads (14%) | called by muse, varscan2
- CCDC39 | c.2266-518G>A | Intron (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+16del | Intron (DEL) | VAF 30/214 reads (14%) | called by mutect2, pindel, varscan2
- ENKUR | c.765-41T>A | Intron (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- LDHA | chr11:18394610 C>T | 5'Flank (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- LEKR1 | c.*1422A>G | 3'UTR (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- MAPK13 | c.841+9C>T | Intron (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- MIR1302-7 | n.49C>A | RNA (SNP) | VAF 18/233 reads (8%) | called by muse, mutect2
- MIR184 | n.64C>G | RNA (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- PPP1R7 | c.819+661C>T | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- SH2D4B | c.184+2407C>T | Intron (SNP) | VAF 49/438 reads (11%) | catalogued as rs778208985; called by muse, mutect2, varscan2
- SPATA31C2 | n.1095C>T | RNA (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- TAGLN3 | c.*24G>C | 3'UTR (SNP) | VAF 53/428 reads (12%) | called by muse, mutect2, varscan2
- TCERG1 | c.-5C>G | 5'UTR (SNP) | VAF 14/202 reads (7%) | catalogued as COSV99694702; called by muse, mutect2
- TMEM232 | c.903-4219C>T | Intron (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- USP46 | c.36+2772A>G | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
